Somatic mutation profile of tumor specimen C3N-01008-02 (aliquot CPT0095130010) from CPTAC case C3N-01008, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 68.2 years (24,919 days).
Specimen C3N-01008-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 195c1fa3-0d49-4546-bf08-74b4c48c65b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01008-31 (Blood Derived Normal), aliquot CPT0095170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba73901f-3379-4137-9849-b167db1d838b

The open-access MAF lists 117 somatic variants for this specimen: 77 protein-altering or splice-affecting, 24 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 24, RNA 5, Nonsense Mutation 5, Intron 4, 5'UTR 4, 3'UTR 3, Frame Shift Ins 2, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.97T>G p.S33A | Missense Mutation (SNP) | VAF 70/350 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519886, COSV62688086, COSV62689225, COSV62704131; ClinVar: likely pathogenic; called by muse, varscan2
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 62/435 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 35/87 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 72/166 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.692); catalogued as rs121913528, COSV55499283, COSV55796966; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- NSD1 | c.3964C>T p.R1322* | Nonsense Mutation (SNP) | VAF 55/167 reads (33%) | catalogued as rs587784107, CM033419; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1393_1401del p.R465_Y467del (on ENST00000521381 / NM_181523.3; = p.R195_Y197del on NM_181504.4) | In Frame Del (DEL) | VAF 49/169 reads (29%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ACVR1B | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 44/97 reads (45%) | catalogued as rs1433185698; called by muse, mutect2, varscan2
- ADAMTS16 | c.2750C>T p.T917M | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs192673903; called by muse, mutect2, varscan2
- ANGPT2 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1258471583; called by muse, mutect2, varscan2
- ANTXR1 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 158/510 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58009595; called by muse, mutect2, varscan2
- AUP1 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 161/287 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.169); catalogued as rs757009295, COSV51212038; called by muse, mutect2, varscan2
- CPN1 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 82/438 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs940408104; called by muse, mutect2, varscan2
- DNPEP | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 150/248 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs765499069, COSV56111791; called by muse, mutect2, varscan2
- ERBB4 | c.2575A>G p.I859V | Missense Mutation (SNP) | VAF 50/345 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs1279305501; called by muse, mutect2, varscan2
- FAM50B | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs1382447513; called by muse, mutect2, varscan2
- FUT3 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 180/457 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs201508055; called by muse, mutect2, varscan2
- HIVEP3 | c.5987G>A p.R1996Q | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs767289271, COSV99914150; called by muse, mutect2, varscan2
- JAKMIP3 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 107/301 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs908104354; called by muse, mutect2, varscan2
- KIRREL2 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 72/184 reads (39%) | catalogued as rs781353593; called by muse, mutect2, varscan2
- KLHL4 | c.1441G>A p.V481M | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781018361, COSV64142272; called by muse, mutect2, varscan2
- LRP5 | c.3637T>C p.S1213P | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.106); catalogued as rs772741983; called by muse, mutect2, varscan2
- MED1 | c.229A>G p.M77V | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.199); catalogued as rs770561661; called by muse, mutect2, varscan2
- NLRP1 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.254); catalogued as rs754740745; called by muse, mutect2
- NR2E1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 136/375 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.049); catalogued as rs776107849; called by muse, mutect2, varscan2
- NSD1 | c.6635C>A p.P2212H | Missense Mutation (SNP) | VAF 187/458 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100729579, COSV61773156; called by muse, mutect2, varscan2
- OR10G9 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.042); catalogued as rs201447659, COSV66686415; called by muse, mutect2, varscan2
- PACS2 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.038); catalogued as rs781996736, COSV57654564; called by muse, mutect2, varscan2
- PCDHGB7 | c.1727A>G p.D576G | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV53969611; called by muse, mutect2, varscan2
- PCLO | c.12259C>T p.R4087W | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs748708109; called by muse, mutect2
- PGAM4 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV58445940; called by muse, mutect2, varscan2
- PHYHIP | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58687949; called by muse, mutect2, varscan2
- POU6F2 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1318441973; called by muse, mutect2, varscan2
- PTEN | c.95T>G p.I32S | Missense Mutation (SNP) | VAF 150/180 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM110156, COSV64298840; called by muse, mutect2, varscan2
- SCN3A | c.2551C>T p.R851* | Nonsense Mutation (SNP) | VAF 76/232 reads (33%) | catalogued as rs1363400927, COSV51806492; called by muse, mutect2, varscan2
- SEMA3G | c.1682G>C p.R561P | Missense Mutation (SNP) | VAF 71/323 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51596118; called by muse, mutect2, varscan2
- SLC16A2 | c.268C>G p.R90G | Missense Mutation (SNP) | VAF 88/217 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1212806180; called by muse, mutect2, varscan2
- SLC5A4 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 99/266 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138159172; called by muse, mutect2, varscan2
- SPOP | c.350T>C p.M117T | Missense Mutation (SNP) | VAF 104/254 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.386); catalogued as COSV61654563; called by muse, mutect2, varscan2
- SPTBN2 | c.4747C>T p.R1583* | Nonsense Mutation (SNP) | VAF 139/314 reads (44%) | catalogued as rs766400529; called by muse, mutect2, varscan2
- SRRM3 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs782795402, COSV58391193; called by muse, mutect2, varscan2
- STK11IP | c.3149G>A p.R1050H | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as rs531254740, COSV55251890, COSV99822503; called by muse, mutect2, varscan2
- TNS3 | c.2221C>T p.R741W | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs777401189, COSV60788238; called by muse, mutect2, varscan2
- TTLL4 | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 87/274 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1328234813; called by muse, mutect2, varscan2
- ZBTB7B | c.1087C>T p.R363C (on ENST00000292176; = p.R397C on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/170 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52692535; called by muse, mutect2, varscan2
- ANGPT2 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ARFGEF3 | c.718A>G p.S240G | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ARHGAP26 | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP6 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.449); called by muse, mutect2
- ARMCX2 | c.713C>A p.S238Y | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARMCX2 | c.712T>C p.S238P | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATG5 | c.748C>G p.P250A | Missense Mutation (SNP) | VAF 100/266 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- BCOR | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 139/298 reads (47%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- C2CD5 | c.2372C>T p.A791V | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- EPHB2 | c.1125C>G p.C375W | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EYA2 | c.1379T>C p.L460P | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGF22 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRY | c.1527G>T p.L509F | Missense Mutation (SNP) | VAF 108/235 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- IRX2 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 45/348 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRP8 | c.1097del p.F366Sfs*45 | Frame Shift Del (DEL) | VAF 82/243 reads (34%) | called by mutect2, pindel, varscan2
- MAGEC3 | c.1540A>C p.T514P | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- MYBBP1A | c.3312C>G p.D1104E | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- NAV2 | c.6286T>G p.S2096A (on ENST00000396087 / NM_001244963.2; = p.S2037A on NM_145117.5) | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEURL1B | c.1160C>T p.T387M | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OR5M10 | c.627C>A p.S209R | Missense Mutation (SNP) | VAF 102/251 reads (41%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- SAMHD1 | c.1018G>T p.V340F | Missense Mutation (SNP) | VAF 157/419 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SETD2 | c.4940G>A p.R1647K | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC12A2 | c.1607T>C p.I536T | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.338); called by muse, mutect2
- SLC19A3 | c.91T>C p.S31P | Missense Mutation (SNP) | VAF 102/420 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- STK3 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 102/190 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- STRN3 | c.1831dup p.R611Kfs*19 (on ENST00000357479 / NM_001083893.2; = p.R527Kfs*19 on NM_014574.4) | Frame Shift Ins (INS) | VAF 57/177 reads (32%) | called by mutect2, pindel, varscan2
- TRMT61B | c.1205dup p.N402Kfs*11 | Frame Shift Ins (INS) | VAF 43/201 reads (21%) | called by mutect2, pindel, varscan2
- UFSP2 | c.1276G>T p.D426Y | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- XDH | c.1655A>G p.K552R | Missense Mutation (SNP) | VAF 16/436 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2
- ZFP37 | c.305G>T p.C102F | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF174 | c.252G>C p.Q84H | Missense Mutation (SNP) | VAF 102/256 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF41 | c.430C>A p.L144I | Missense Mutation (SNP) | VAF 114/317 reads (36%) | SIFT tolerated (1); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZSWIM4 | c.2404C>T p.H802Y | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- AC138647.1 | c.306C>T p.R102= | Silent (SNP) | VAF 163/240 reads (68%) | called by muse, mutect2, varscan2
- ATP6V0A4 | c.2514C>G p.A838= | Silent (SNP) | VAF 43/393 reads (11%) | called by muse, mutect2, varscan2
- ATP7B | c.3909T>C p.D1303= | Silent (SNP) | VAF 30/752 reads (4%) | called by muse, mutect2
- C7orf57 | c.540G>T p.L180= | Silent (SNP) | VAF 110/387 reads (28%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.3558G>A p.A1186= | Silent (SNP) | VAF 44/181 reads (24%) | catalogued as rs764532960, COSV70487736; called by muse, mutect2, varscan2
- FAM9A | c.138C>T p.P46= | Silent (SNP) | VAF 79/177 reads (45%) | catalogued as rs751592118, COSV66812977; called by muse, mutect2, varscan2
- HLA-G | c.63G>A p.E21= | Silent (SNP) | VAF 15/124 reads (12%) | called by muse, mutect2, varscan2
- HSPA1L | c.684T>A p.T228= | Silent (SNP) | VAF 45/275 reads (16%) | catalogued as rs111381223, COSV65148869; called by muse, mutect2, varscan2
- IGLV1-47 | c.87G>A p.A29= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as rs201548889; called by muse, mutect2, varscan2
- IRX2 | c.1158G>A p.S386= | Silent (SNP) | VAF 131/333 reads (39%) | catalogued as rs1288354493, COSV57409904; called by muse, mutect2, varscan2
- KMT2D | c.7500G>A p.A2500= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs201604988; called by muse, mutect2, varscan2
- KNTC1 | c.4818A>G p.K1606= | Silent (SNP) | VAF 75/164 reads (46%) | called by muse, mutect2, varscan2
- KRT40 | c.57C>T p.S19= | Silent (SNP) | VAF 81/182 reads (45%) | catalogued as rs1408211056; called by muse, mutect2, varscan2
- MFAP3L | c.72T>G p.T24= | Silent (SNP) | VAF 105/243 reads (43%) | called by muse, mutect2, varscan2
- MYH1 | c.3852G>C p.L1284= | Silent (SNP) | VAF 110/231 reads (48%) | called by muse, mutect2, varscan2
- OLFM1 | c.243G>A p.Q81= (on ENST00000371793 / NM_001282611.2; = p.Q63= on NM_006334.4) | Silent (SNP) | VAF 62/151 reads (41%) | called by muse, mutect2, varscan2
- PSRC1 | c.300C>T p.G100= | Silent (SNP) | VAF 71/157 reads (45%) | catalogued as rs558602891; called by muse, mutect2, varscan2
- RNF128 | c.882G>A p.T294= (on ENST00000255499 / NM_194463.2; = p.T268= on NM_024539.3) | Silent (SNP) | VAF 60/147 reads (41%) | catalogued as rs367623563, COSV55253617; called by muse, mutect2, varscan2
- SLC25A52 | c.699C>T p.A233= (on ENST00000672005; = p.A223= on NM_001034172.4) | Silent (SNP) | VAF 86/237 reads (36%) | catalogued as rs928222122, COSV52502252; called by muse, mutect2, varscan2
- TAMM41 | c.945A>C p.T315= | Silent (SNP) | VAF 35/188 reads (19%) | catalogued as COSV56073436; called by muse, mutect2, varscan2
- TPTE | c.1650C>T p.S550= (on ENST00000618007 / NM_199261.4; = p.S532= on NM_199259.4) | Silent (SNP) | VAF 74/322 reads (23%) | catalogued as rs774949669; called by muse, mutect2, varscan2
- USP22 | c.465T>G p.L155= | Silent (SNP) | VAF 125/287 reads (44%) | called by muse, mutect2, varscan2
- WIPF1 | c.759G>A p.P253= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs1032410011; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF239 | c.1164G>A p.S388= | Silent (SNP) | VAF 61/168 reads (36%) | catalogued as rs752110565; called by muse, mutect2, varscan2
- CNP | c.*2779A>G | 3'UTR (SNP) | VAF 15/265 reads (6%) | called by muse, mutect2
- ESPNP | n.1495_1497dup | RNA (INS) | VAF 8/92 reads (9%) | catalogued as rs570730210; called by mutect2, pindel
- FBXL21P | n.1543C>G | RNA (SNP) | VAF 38/177 reads (21%) | called by muse, mutect2, varscan2
- FGFR2 | c.*3G>T | 3'UTR (SNP) | VAF 93/237 reads (39%) | catalogued as COSV100336031, COSV60640216; called by muse, mutect2, varscan2
- KCNA1 | c.-43C>T | 5'UTR (SNP) | VAF 36/100 reads (36%) | catalogued as rs1274645611; called by muse, mutect2, varscan2
- NAP1L6P | n.452C>A | RNA (SNP) | VAF 43/206 reads (21%) | called by muse, mutect2, varscan2
- OFCC1 | n.105C>A | RNA (SNP) | VAF 72/201 reads (36%) | called by muse, mutect2, varscan2
- PIH1D1 | c.337+251C>G | Intron (SNP) | VAF 48/102 reads (47%) | called by muse, mutect2, varscan2
- POU1F1 | c.143-22G>C | Intron (SNP) | VAF 27/159 reads (17%) | called by muse, mutect2, varscan2
- SATL1 | c.-557A>G | 5'UTR (SNP) | VAF 15/94 reads (16%) | called by mutect2, varscan2
- SRPX2 | c.163+22G>A | Intron (SNP) | VAF 76/186 reads (41%) | catalogued as rs777018752; called by muse, mutect2, varscan2
- TLCD3B | c.540+70G>T | Intron (SNP) | VAF 65/329 reads (20%) | called by muse, mutect2, varscan2
- TNFAIP8 | c.-62C>G | 5'UTR (SNP) | VAF 60/160 reads (38%) | called by muse, mutect2, varscan2
- TPRXL | n.1155G>A | RNA (SNP) | VAF 21/180 reads (12%) | catalogued as rs1013021437; called by muse, mutect2, varscan2
- UMPS | c.*4624G>A | 3'UTR (SNP) | VAF 34/84 reads (40%) | catalogued as rs745376300; called by muse, mutect2, varscan2
- ZNF264 | c.-10G>T | 5'UTR (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
